Somatic mutation profile of tumor specimen TCGA-VP-A876-01A (aliquot TCGA-VP-A876-01A-11D-A34U-08) from TCGA case TCGA-VP-A876, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 46.4 years (16,934 days).
Specimen TCGA-VP-A876-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80b72957-2eff-41fd-a711-192ff1329556.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A876-10A (Blood Derived Normal), aliquot TCGA-VP-A876-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2498ee1-7b25-4603-b228-5dd8575bf9bb

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 13/16 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM942136, COSV52661418, COSV52925998, COSV53589174; called by muse, mutect2, varscan2
- ADAM11 | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV99567542; called by muse, mutect2, varscan2
- BMI1 | c.168T>A p.C56* | Nonsense Mutation (SNP) | VAF 80/219 reads (37%) | catalogued as COSV100936416; called by muse, mutect2, varscan2
- CFAP45 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774486512, COSV63650344; called by muse, mutect2, varscan2
- CLPTM1L | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs959649220, COSV100307117; called by muse, mutect2, varscan2
- DMRT2 | c.1577T>C p.F526S | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.794); catalogued as rs746218872, COSV99426129; called by muse, mutect2, varscan2
- GABBR2 | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV99410399; called by muse, mutect2, varscan2
- LARGE1 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.459); catalogued as rs760530978, COSV100505592; called by muse, mutect2, varscan2
- OR5A1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 91/254 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118386; called by muse, mutect2, varscan2
- PHLPP2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs867120820, COSV62423506; called by muse, mutect2
- PLCB4 | c.2226G>C p.M742I | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.125); catalogued as rs1004438313, COSV99595799; called by muse, mutect2
- RETSAT | c.1795C>T p.L599F | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV99805793; called by muse, mutect2
- SCN5A | c.6017C>A p.P2006H (on ENST00000333535 / NM_198056.3; = p.P2005H on NM_000335.5) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.161); catalogued as CD120692, COSV100348914; called by mutect2, varscan2
- SPECC1L | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100062583; called by muse, varscan2
- SSBP1 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as rs760601343, COSV54681106; called by muse, mutect2
- VEGFD | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV52909089, COSV99938450; called by mutect2, varscan2
- VPS13D | c.11588A>G p.Q3863R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99167123; called by muse, mutect2, varscan2
- ZNF182 | c.1756A>G p.T586A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV100527090; called by muse, mutect2, varscan2
- ZNF790 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs200810061; called by muse, mutect2, varscan2
- FSCN3 | c.260_295del p.P87_F99delinsL | In Frame Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- TNFSF12 | c.608T>A p.L203H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); called by muse, mutect2
- ARSH | c.807C>T p.H269= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs748712566, COSV101139893; called by muse, mutect2, varscan2
- COL14A1 | c.1836A>T p.S612= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV52852931; called by muse, mutect2, varscan2
- GCN1 | c.7557G>A p.A2519= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs372015112; called by muse, mutect2, varscan2
- SIRPB1 | c.390C>T p.D130= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs1395199148, COSV99498440; called by muse, mutect2
- TGFB1I1 | c.270C>T p.L90= (on ENST00000394863 / NM_001042454.3; = p.L73= on NM_015927.4) | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as rs1398380486, COSV100691109; called by muse, mutect2
- YAE1 | c.25T>C p.L9= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99784967; called by muse, mutect2, varscan2
